Gene-level copy-number profile of specimen HCM-BROD-0138-C25-85B from HCMI case HCM-BROD-0138-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 66.5 years (24,299 days).
Specimen HCM-BROD-0138-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 37e5b623-9199-4cf4-8f27-97ffa8d79779.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0138-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/0fa2f551-f2f4-4b65-b28e-1b03f770e778

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,891; copy number 2: 15,270; copy number 3: 19,417; copy number 4: 16,120; copy number 5: 3,907; copy number 6: 1,533; copy number 7: 406; copy number 8: 335; copy number 13: 26; copy number 22: 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 769 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:166,569,693–198,123,232, 604 genes, copy number 7–8 (broad region; genes not listed).
- chr6:61,679,961–63,443,580, 13 genes, copy number 7–8 (within-gene range 5–8): KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1.
- chr9:43,109,866–61,789,426, 21 genes, copy number 8: FP325317.1, FP325317.2, BX088702.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P.
- chr9:61,861,625–61,911,022, 6 genes, copy number 8: AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E.
- chr12:20,014,780–26,335,856, 97 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr21:7,744,962–8,680,934, 28 genes, copy number 13–22: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2.

Autosomal genes at a single copy (total copy number 1): 156. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
